Somatic mutation profile of tumor specimen BA2276D (aliquot aq-BA2276D) from BEATAML1.0 case 2294, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.0 years (29,235 days).
Specimen BA2276D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31a8b463-7f47-458c-925c-b5601046f9a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2170D (Solid Tissue Normal), aliquot aq-BA2170D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2737719-ae4e-4635-b1b3-8d8b16765e41

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, RNA 2, Silent 2, Frame Shift Del 1, 5'UTR 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAP2 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs367682004; called by mutect2, varscan2
- DNAH9 | c.10877G>A p.R3626H | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as rs183636309; called by muse, mutect2
- LRFN4 | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV58920664; called by muse, mutect2
- MTA2 | c.866A>T p.D289V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377278798; called by muse, mutect2, varscan2
- NTNG2 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV62368063; called by muse, mutect2, varscan2
- RBFOX3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1294363374, COSV101332134; ClinVar: uncertain significance; called by muse, varscan2
- RCOR2 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1480484973; called by muse, mutect2
- SPRY3 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs746591994, COSV99044158; called by mutect2, varscan2
- ZIC3 | c.389C>A p.A130E | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.265); catalogued as COSV54976654; called by muse, mutect2
- EFR3A | c.545A>G p.D182G | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- LPA | c.4714del p.E1572Sfs*5 | Frame Shift Del (DEL) | VAF 62/125 reads (50%) | called by mutect2, varscan2
- MUC17 | c.10913C>A p.T3638N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PI4KA | c.5531G>A p.W1844* | Nonsense Mutation (SNP) | VAF 79/182 reads (43%) | called by mutect2, varscan2
- WDR73 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ABCC11 | c.3204C>T p.G1068= | Silent (SNP) | VAF 61/111 reads (55%) | called by muse, mutect2, varscan2
- NEURL4 | c.2535C>T p.H845= | Silent (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- OR4C4P | n.373G>A | RNA (SNP) | VAF 31/71 reads (44%) | catalogued as rs755458181; called by muse, mutect2, varscan2
- PBLD | c.-5G>T | 5'UTR (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- SNORD115-33 | n.37C>T | RNA (SNP) | VAF 34/110 reads (31%) | catalogued as rs200561707; called by muse, mutect2, varscan2
- SYCE1 | chr10:133568255 C>T | 5'Flank (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
